Somatic mutation profile of tumor specimen TCGA-HU-8602-01A (aliquot TCGA-HU-8602-01A-11D-2394-08) from TCGA case TCGA-HU-8602, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.9 years (21,522 days).
Specimen TCGA-HU-8602-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a5ab0d-f04a-4aed-b346-32d49275c4e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8602-10A (Blood Derived Normal), aliquot TCGA-HU-8602-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90a69959-56af-4292-8864-63c547552f77

The open-access MAF lists 1,963 somatic variants for this specimen: 1,471 protein-altering or splice-affecting, 433 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 936, Silent 433, Frame Shift Del 384, Frame Shift Ins 56, Nonsense Mutation 45, Splice Site 26, Intron 19, RNA 18, In Frame Del 16, 5'Flank 8, 5'UTR 6, Splice Region 6.

Variants (750 of 1,963; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.2835dup p.D946Rfs*13 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | catalogued as rs80359356; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.3787dup p.V1263Gfs*4 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | catalogued as rs869312877; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6074del p.G2025Afs*181 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs886041417, CM071643, CM970377, COSV60392353; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DCDC2 | c.529del p.I177Sfs*3 | Frame Shift Del (DEL) | VAF 62/274 reads (23%) | catalogued as rs904944428; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 33/153 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774589520, COSV57247786; called by muse, mutect2, varscan2
- FBN1 | c.4588C>T p.R1530C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs111401431, CM013928, COSV100355554, COSV57310752; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.860A>T p.E287V (on ENST00000281708 / NM_001349798.2; = p.E207V on NM_018315.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55897632; called by muse, mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 48/163 reads (29%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 17/108 reads (16%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RORA | c.1385G>A p.R462Q (on ENST00000335670 / NM_134261.3; = p.R487Q on NM_002943.3) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs1433850094, COSV55035622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 43/206 reads (21%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SPART | c.696dup p.V233Cfs*8 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TSC1 | c.2672del p.N891Tfs*40 | Frame Shift Del (DEL) | VAF 48/263 reads (18%) | catalogued as rs118203724, CD1111250, COSV53764493; ClinVar: not provided / pathogenic; called by pindel, varscan2
- TULP1 | c.1495+1G>A p.X499_splice | Splice Site (SNP) | VAF 34/113 reads (30%) | catalogued as rs281865168, CS982391, COSV57692020; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VCL | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as rs397517244, CM1410942, COSV53007237; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.2732C>T p.T911M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs747318337, COSV52218275; called by muse, mutect2, varscan2
- ABCA13 | c.4778T>C p.V1593A | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs774675807, COSV70026154; called by muse, mutect2, varscan2
- ABCA13 | c.6988del p.S2330Qfs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs35914499; called by mutect2, varscan2
- ABCA13 | c.14170A>G p.S4724G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV68943974; called by muse, mutect2, varscan2
- ABCC1 | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV60681369; called by muse, mutect2, varscan2
- ABCC12 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs372957171; called by muse, mutect2, varscan2
- ABCC2 | c.890del p.K297Rfs*14 | Frame Shift Del (DEL) | VAF 42/206 reads (20%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCG1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1445295054, COSV59201332; called by muse, mutect2, varscan2
- ABHD16A | c.478T>G p.F160V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV65451434; called by muse, mutect2, varscan2
- ABI2 | c.1102T>A p.S368T (on ENST00000295851 / NM_001375719.1; = p.S301T on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.986); catalogued as rs1366434179, COSV53690226; called by muse, mutect2, varscan2
- ABL1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs766145624, COSV59325968; called by mutect2, varscan2
- ABLIM1 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs780339538, COSV53301046; called by muse, mutect2, varscan2
- ACACB | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs140156252; called by muse, mutect2, varscan2
- ACAN | c.6917del p.P2306Lfs*10 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs777726601; called by mutect2, pindel
- ACIN1 | c.1792A>G p.S598G | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs772662866, COSV52973808; called by muse, mutect2, varscan2
- ACOT11 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 41/155 reads (26%) | catalogued as rs777875503, COSV59346527; called by muse, mutect2, varscan2
- ACP5 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs778805198, COSV54535415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as rs376869655; called by muse, mutect2, varscan2
- ACVR1C | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV54644170; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 52/105 reads (50%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.133); catalogued as rs377327401; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS12 | c.2429A>G p.Y810C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61256720; called by muse, mutect2, varscan2
- ADAMTS14 | c.3229G>A p.D1077N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs778072854, COSV64600024; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774772996, COSV54438263; called by muse, mutect2, varscan2
- ADCK1 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53078857; called by muse, mutect2, varscan2
- ADD2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52455754; called by muse, mutect2, varscan2
- ADGRB3 | c.1052G>T p.W351L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV65384968; called by muse, mutect2, varscan2
- ADGRB3 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53236298; called by muse, mutect2, varscan2
- ADGRB3 | c.4469C>T p.T1490I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV53236312; called by muse, mutect2, varscan2
- ADGRF5 | c.3088T>C p.C1030R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51930499; called by muse, mutect2, varscan2
- ADGRG2 | c.1192G>A p.A398T (on ENST00000379869 / NM_001079858.3; = p.A395T on NM_005756.4) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV61337791; called by muse, mutect2, varscan2
- ADGRG5 | c.608dup p.W204Lfs*4 | Frame Shift Ins (INS) | VAF 20/98 reads (20%) | catalogued as rs750862917; called by mutect2, varscan2
- ADGRL4 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV66059719; called by muse, mutect2, varscan2
- ADGRV1 | c.14276A>G p.D4759G | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV67979537; called by muse, mutect2, varscan2
- ADRB3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs201607471, COSV61461528; called by muse, mutect2, varscan2
- AEBP1 | c.2440T>C p.W814R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56255770; called by muse, mutect2, varscan2
- AFDN | c.4271C>T p.A1424V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.993); catalogued as COSV60038770; called by muse, mutect2, varscan2
- AFF2 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 61/289 reads (21%) | catalogued as COSV53978826; called by muse, mutect2, varscan2
- AGAP4 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); catalogued as rs1422901360; called by muse, mutect2, varscan2
- AGMAT | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1197543488, COSV65435643; called by muse, mutect2
- AGO1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1385910631, COSV64594759; called by muse, mutect2, varscan2
- AGPAT3 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs762855528, COSV52368167; called by muse, mutect2, varscan2
- AGRN | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs778548788, COSV65068055; called by muse, mutect2, varscan2
- AGTPBP1 | c.1264T>C p.Y422H (on ENST00000357081 / NM_001330701.2; = p.Y382H on NM_015239.2) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV61268998; called by muse, mutect2, varscan2
- AHNAK2 | c.15563G>A p.S5188N | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.215); catalogued as COSV60909088; called by muse, mutect2, varscan2
- AJM1 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs761802107, COSV56031952; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKNA | c.3803C>T p.T1268I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs776377854, COSV56335240; called by muse, mutect2, varscan2
- AL136295.1 | c.1960T>C p.C654R | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55778404; called by muse, mutect2, varscan2
- ALG10 | c.284T>C p.M95T | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56791829; called by muse, mutect2, varscan2
- ALG12 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | PolyPhen possibly damaging (0.881); catalogued as rs751915470, COSV58206372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs780661069, COSV53173823; called by muse, mutect2, varscan2
- ALOX5 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.386); catalogued as rs1273771379, COSV65551297; called by muse, mutect2, varscan2
- ALPK2 | c.4501G>A p.G1501S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as rs748622515, COSV64490638; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 50/296 reads (17%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMER1 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57655692; called by muse, mutect2, varscan2
- AMOT | c.2363T>C p.L788P (on ENST00000371959 / NM_001113490.1; = p.L379P on NM_133265.3) | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59060952; called by muse, mutect2, varscan2
- ANGPT1 | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52432330; called by muse, mutect2, varscan2
- ANK3 | c.8713C>T p.R2905C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs757636476, COSV55046882; called by muse, mutect2, varscan2
- ANKIB1 | c.2282A>G p.E761G | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56059073; called by muse, mutect2, varscan2
- ANKRD24 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV53668215; called by muse, mutect2
- ANKRD44 | c.2816del p.N939Ifs*16 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1408961377; called by pindel, varscan2*
- ANKS6 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62049183; called by muse, mutect2, varscan2
- ANO5 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs750702622, COSV61082151; called by muse, mutect2, varscan2
- ANO7 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs201638265, COSV51468946; called by muse, mutect2, varscan2
- ANOS1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as rs1205589697, COSV52916553; called by muse, mutect2, varscan2
- AP1S2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV57063747; called by muse, mutect2, varscan2
- APC2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs771794817, COSV52016442; called by muse, mutect2, varscan2
- AQP4 | c.605T>C p.L202S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67218304, COSV67218657; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGEF1 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51603447; called by muse, mutect2, varscan2
- ARG2 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53619167; called by muse, mutect2, varscan2
- ARHGAP6 | c.1691A>G p.H564R | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV57292312; called by muse, mutect2, varscan2
- ARHGEF1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100528892, COSV61526505; called by muse, mutect2, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2, varscan2
- ARHGEF15 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866909786, COSV62724502; called by muse, mutect2, varscan2
- ARHGEF40 | c.4532C>T p.A1511V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV53878510; called by muse, mutect2, varscan2
- ARID1B | c.2841-2A>G p.X947_splice | Splice Site (SNP) | VAF 60/229 reads (26%) | catalogued as COSV51650781; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs753865255; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.4546C>T p.R1516C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1002567758, COSV64205926; called by muse, mutect2, varscan2
- ASPM | c.4285T>C p.S1429P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV54125682; called by muse, mutect2, varscan2
- ASXL1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60102435; called by muse, mutect2, varscan2
- ATAD2 | c.1269A>G p.V423= | Splice Region (SNP) | VAF 23/199 reads (12%) | catalogued as rs748345203, COSV54877964; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG5 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV58346326; called by muse, mutect2, varscan2
- ATMIN | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55145299; called by muse, mutect2, varscan2
- ATP11B | c.3358A>G p.M1120V | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV60026597; called by muse, mutect2, varscan2
- ATP1A4 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV63625677; called by muse, mutect2, varscan2
- ATP5F1B | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV51632601; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs745565784, COSV52871173; called by muse, mutect2, varscan2
- ATP6V1H | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs201536132; called by muse, mutect2, varscan2
- ATP8B4 | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99464802; called by muse, mutect2, varscan2
- ATXN2L | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs137943525; called by muse, mutect2, varscan2
- AUTS2 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs1455506276, COSV61385920; called by muse, mutect2, varscan2
- AUTS2 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV61385925; called by muse, mutect2, varscan2
- AXL | c.2021C>T p.A674V (on ENST00000301178 / NM_021913.5; = p.A665V on NM_001699.6) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs984694773, COSV56564451; called by muse, mutect2, varscan2
- AXL | c.2257G>A p.V753M (on ENST00000301178 / NM_021913.5; = p.V744M on NM_001699.6) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372169583, COSV56572090; called by muse, mutect2, varscan2
- B3GALT4 | c.725dup p.R243Qfs*108 | Frame Shift Ins (INS) | VAF 21/114 reads (18%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- B9D2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV54683643; called by muse, mutect2, varscan2
- BAHD1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs578160651, COSV69083688; called by muse, mutect2, varscan2
- BAIAP2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58333610; called by muse, mutect2, varscan2
- BAIAP2L2 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59268238; called by muse, mutect2, varscan2
- BCL9L | c.3427A>G p.S1143G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52682352; called by muse, mutect2
- BEGAIN | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV62068134; called by muse, mutect2, varscan2
- BEND4 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1560574009, COSV72468959; called by muse, mutect2, varscan2
- BICD1 | c.2749A>G p.T917A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.057); catalogued as COSV55675357; called by muse, mutect2
- BIRC6 | c.11820del p.R3941Gfs*7 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as COSV101427757; called by mutect2, pindel, varscan2
- BIRC7 | c.827C>T p.A276V (on ENST00000217169 / NM_139317.3; = p.A258V on NM_022161.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53900499; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BMP2K | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs752366508, COSV55008423; called by muse, mutect2, varscan2
- BRMS1L | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1023777427, COSV53762371; called by muse, mutect2, varscan2
- BSND | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780910610, COSV64870300; called by muse, mutect2, varscan2
- BSX | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV100545258, COSV58005158; called by muse, mutect2, varscan2
- BTBD7 | c.2530A>G p.T844A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58283930; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as rs752512017; called by mutect2, varscan2
- C11orf49 | c.217del p.H73Tfs*24 | Frame Shift Del (DEL) | VAF 29/154 reads (19%) | catalogued as rs780813798; called by mutect2, pindel, varscan2
- C16orf78 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV54555214; called by muse, mutect2, varscan2
- C19orf44 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.153); catalogued as COSV55610521, COSV55613411; called by muse, mutect2, varscan2
- C2CD2L | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60883712; called by muse, mutect2, varscan2
- C2orf66 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV61098604; called by muse, mutect2, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs750770711, COSV99837243; called by mutect2, pindel, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs747591930; called by mutect2, varscan2
- C8B | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV64776638; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 21/190 reads (11%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CAB39L | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1456695820, COSV61713810; called by muse, mutect2, varscan2
- CACNA1C | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59699996; called by muse, mutect2, varscan2
- CACNA1C | c.4032G>T p.E1344D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV59700014; called by muse, mutect2
- CACNA1D | c.5399G>C p.S1800T (on ENST00000350061 / NM_001128840.3; = p.S1820T on NM_000720.4) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV55439346, COSV99857610; called by muse, mutect2, varscan2
- CACNA1F | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV59903290; called by muse, mutect2, varscan2
- CACNA2D1 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62374008; called by muse, mutect2
- CACNB4 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs796052287, COSV52389822; ClinVar: uncertain significance; called by muse, mutect2
- CACNG1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56826148; called by muse, mutect2, varscan2
- CACTIN | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs763298025, COSV50266935; called by muse, mutect2, varscan2
- CAD | c.4202G>T p.G1401V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53024189, COSV53031035; called by muse, mutect2, varscan2
- CADM1 | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59004346; called by muse, mutect2, varscan2
- CADPS | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as rs772497329, COSV51869359; called by muse, mutect2, varscan2
- CALHM5 | c.738dup p.E247* | Frame Shift Ins (INS) | VAF 32/105 reads (30%) | catalogued as rs768528441; called by mutect2, varscan2
- CALM1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV63662693; called by muse, mutect2, varscan2
- CAND2 | c.3401G>A p.R1134Q (on ENST00000456430 / NM_001162499.2; = p.R1017Q on NM_012298.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759425363, COSV55987282; called by muse, mutect2
- CAPN1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54196978; called by muse, mutect2, varscan2
- CAPN2 | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV54334668; called by muse, mutect2, varscan2
- CARD11 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1053219257, COSV67797339; called by muse, mutect2, varscan2
- CARMIL2 | c.3245C>T p.A1082V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54666203; called by muse, mutect2
- CARMIL3 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs749594894, COSV57725226; called by muse, mutect2, varscan2
- CASD1 | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV51970982; called by muse, varscan2
- CASKIN2 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58690098; called by muse, mutect2, varscan2
- CASP8 | c.1228_1229del p.V410Ffs*28 (on ENST00000432109 / NM_033355.3; = p.V427Ffs*28 on NM_001228.4) | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs587776665; called by pindel, varscan2
- CATSPER2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs752528849, COSV58660220; called by muse, mutect2, varscan2
- CATSPER2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.514); catalogued as COSV100390697; called by muse, mutect2, varscan2
- CATSPER3 | c.198del p.F66Lfs*10 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | catalogued as CM110786; called by mutect2, pindel, varscan2
- CBX2 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53968565; called by muse, mutect2, varscan2
- CBX5 | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV52935791; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 32/215 reads (15%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC141 | c.2225A>G p.Q742R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55369448; called by muse, mutect2, varscan2
- CCDC150 | c.3217T>C p.S1073P | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1396089109, COSV55872256; called by muse, mutect2, varscan2
- CCDC159 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.012); catalogued as rs764628322, COSV52258865; called by muse, mutect2
- CCDC181 | c.1399del p.M467Wfs*16 (on ENST00000367806 / NM_001300969.1; = p.M466Wfs*16 on NM_021179.2) | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs747743772; called by mutect2, pindel, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC198 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53601467; called by muse, mutect2, varscan2
- CCDC40 | c.2819T>C p.I940T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1314533027, COSV66473076; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC7 | c.3461A>G p.Y1154C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs749927730, COSV56537709; called by muse, mutect2, varscan2
- CCNJL | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57443181; called by muse, mutect2, varscan2
- CCPG1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374529704; called by muse, mutect2, varscan2
- CCT2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as rs545752398, COSV54739266; called by muse, mutect2, varscan2
- CCT8 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs892474753, COSV54502811; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | catalogued as rs780034402; called by mutect2, varscan2
- CD320 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV56848063, COSV56848924; called by muse, mutect2, varscan2
- CD34 | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV60411911; called by muse, mutect2, varscan2
- CD80 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs370971089, COSV51801501; called by muse, mutect2, varscan2
- CD86 | c.775T>C p.C259R (on ENST00000330540 / NM_175862.5; = p.C253R on NM_006889.4) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV52605366; called by muse, mutect2, varscan2
- CDAN1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs373881679; called by muse, mutect2, varscan2
- CDC25A | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1224575878, COSV56769929; called by muse, mutect2, varscan2
- CDC42EP2 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54203100; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs762194001; called by mutect2, varscan2
- CDHR2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs142176546; called by muse, mutect2, varscan2
- CDHR2 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs766756342, COSV56135250; called by muse, mutect2, varscan2
- CDK13 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.728); catalogued as COSV51696915; called by muse, mutect2, varscan2
- CDKAL1 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs1428696004, COSV51180334; called by muse, mutect2, varscan2
- CDR2L | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.053); catalogued as COSV61500690; called by muse, mutect2, varscan2
- CDT1 | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs528610361, COSV56347505; called by muse, mutect2, varscan2
- CEBPZ | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs756220214, COSV52205162; called by muse, mutect2, varscan2
- CELSR3 | c.3505C>T p.L1169F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV50841208; called by muse, mutect2, varscan2
- CEMIP | c.3994C>T p.R1332W | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as rs1313792720, COSV54988892; called by muse, mutect2, varscan2
- CENPJ | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs568294978, COSV67883067; ClinVar: uncertain significance; called by muse, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as COSV100071584; called by mutect2, pindel, varscan2
- CEP20 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs750373731, COSV55383624; called by muse, mutect2, varscan2
- CES4A | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461785987, COSV58652045, COSV58653658; called by muse, mutect2
- CFAP299 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374263426; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP44 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 40/195 reads (21%) | catalogued as rs1256820198, COSV55609177; called by muse, mutect2, varscan2
- CFAP46 | c.7214del p.P2405Lfs*5 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1344439240; called by mutect2, pindel, varscan2
- CFAP65 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766938631, COSV58558638; called by muse, mutect2, varscan2
- CFH | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs773509771, COSV62776437; called by muse, mutect2, varscan2
- CGN | c.1162T>C p.S388P | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); catalogued as COSV54968409; called by muse, mutect2, varscan2
- CHD5 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52409026; called by muse, mutect2
- CHD7 | c.528del p.P178Lfs*33 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV71107689; called by mutect2, pindel, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHL1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56587723; called by muse, mutect2
- CHRDL1 | c.1114G>A p.V372I (on ENST00000372045; = p.V378I on NM_145234.4) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.959); catalogued as rs747422590, COSV54323200; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA2 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1453727330, COSV53556180; called by muse, varscan2
- CHRNA6 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV52378675, COSV52380271; called by muse, mutect2, varscan2
- CHST2 | c.622del p.D208Tfs*13 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | catalogued as COSV100535884; called by mutect2, pindel, varscan2
- CHST2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58884799; called by muse, mutect2
- CIAO1 | c.781T>C p.C261R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55530369; called by muse, mutect2, varscan2
- CILP2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs754770318, COSV52272965; called by muse, mutect2
- CLCNKB | c.1395del p.Y466Mfs*13 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs762878606; called by mutect2, pindel, varscan2
- CLIC2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1032630286, COSV58935736; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.457); catalogued as rs770360744, COSV61611161; called by muse, mutect2, varscan2
- CLSTN1 | c.1045A>G p.M349V (on ENST00000377298 / NM_001009566.3; = p.M339V on NM_014944.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs769214503, COSV63646855; called by muse, mutect2, varscan2
- CLSTN2 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs764350150, COSV71718527; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 24/161 reads (15%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNTLN | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs774016559, COSV52068263, COSV52089091; called by muse, mutect2
- CNTN5 | c.1703T>C p.V568A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54286335; called by muse, mutect2, varscan2
- COL11A1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62174694; called by muse, mutect2, varscan2
- COL17A1 | c.2823G>T p.G941= | Splice Region (SNP) | VAF 18/87 reads (21%) | catalogued as COSV62225500; called by muse, mutect2, varscan2
- COL25A1 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV67646974; called by muse, mutect2, varscan2
- COL4A5 | c.4739C>T p.T1580M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768320352, COSV60356986, COSV60364945; called by muse, mutect2, varscan2
- COL5A1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs768269251, COSV65665787; called by muse, mutect2, varscan2
- COL8A2 | c.793dup p.E265Gfs*77 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | catalogued as rs953375687; called by mutect2, pindel, varscan2
- COLEC11 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52591830; called by muse, mutect2, varscan2
- COPB1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as COSV51446999; called by muse, mutect2, varscan2
- COQ9 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52645195; called by muse, mutect2, varscan2
- CORO1B | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs747383937, COSV58168250; called by muse, mutect2, varscan2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs759241200; called by mutect2, varscan2
- CPA5 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs782440495, COSV62568910; called by muse, mutect2, varscan2
- CPA6 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.916); catalogued as rs1450353409, COSV52722139; called by muse, mutect2, varscan2
- CPNE6 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs754686465, COSV53742770; called by muse, mutect2, varscan2
- CPSF1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs145778551; called by muse, mutect2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CSMD1 | c.5414G>T p.G1805V (on ENST00000520002; = p.G1804V on NM_033225.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59288938, COSV59307722; called by muse, mutect2, varscan2
- CSMD1 | c.2156C>T p.S719L (on ENST00000520002; = p.S718L on NM_033225.6) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs752005533, COSV59288966; called by muse, mutect2
- CSMD2 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as rs777884398, COSV53885258; called by muse, mutect2, varscan2
- CSRNP3 | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV58775656; called by muse, mutect2, varscan2
- CTAGE1 | c.2222del p.P741Qfs*15 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs771653179; called by pindel, varscan2
- CTAGE1 | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV66942998; called by muse, mutect2, varscan2
- CTNNA1 | c.1761del p.F587Lfs*5 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs1273174561; called by mutect2, pindel, varscan2
- CTNNA1 | c.2530C>T p.Q844* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100242096, COSV57070199; called by muse, mutect2, varscan2
- CTNNA2 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.171); catalogued as rs765711976, COSV58137913; called by muse, mutect2, varscan2
- CTNNB1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs1267755116, COSV62691474; called by muse, mutect2, varscan2
- CTSH | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV54984285; called by muse, mutect2, varscan2
- CTSO | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV70808864; called by muse, mutect2, varscan2
- CTSW | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1182288733, COSV57171783; called by muse, mutect2, varscan2
- CTSW | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV57171792; called by muse, mutect2, varscan2
- CUL4A | c.1556G>A p.G519D (on ENST00000375440 / NM_001008895.4; = p.G419D on NM_003589.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV58371525; called by muse, mutect2, varscan2
- CUX2 | c.3935G>A p.G1312D | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55625807; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 37/83 reads (45%) | catalogued as rs745836350; called by mutect2, varscan2
- CYBC1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139347006; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 13/125 reads (10%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP2D6 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370580423; called by muse, mutect2, varscan2
- CYP2W1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV58269409; called by muse, mutect2, varscan2
- DAPK3 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1355283883, COSV56662287; called by muse, mutect2
- DARS2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776992068, COSV53405966; called by muse, mutect2, varscan2
- DBNL | c.1138T>C p.Y380H (on ENST00000448521 / NM_001014436.3; = p.Y381H on NM_014063.7) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV51977240; called by muse, mutect2, varscan2
- DCAF12 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs767663746, COSV63511689; called by muse, mutect2, varscan2
- DCAF12L1 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421252; called by muse, mutect2, varscan2
- DCAF12L2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV63580533; called by muse, mutect2, varscan2
- DCHS1 | c.9598G>A p.D3200N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54996265; called by muse, mutect2, varscan2
- DCLK1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55174627, COSV99709832; called by muse, mutect2, varscan2
- DCSTAMP | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52576461; called by muse, mutect2, varscan2
- DCUN1D1 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1381652953, COSV53043805; called by muse, mutect2, varscan2
- DDX3X | c.592C>T p.R198C (on ENST00000399959; = p.R199C on NM_001356.5) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV67863166; called by muse, mutect2, varscan2
- DEPDC5 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764876578, COSV56692274, COSV99835805; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DHCR7 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62794536; called by muse, mutect2, varscan2
- DHDDS | c.945G>T p.Q315H (on ENST00000236342 / NM_001319959.1; = p.Q316H on NM_024887.3) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.155); catalogued as COSV52575701; called by muse, varscan2
- DHX15 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV61025865; called by muse, mutect2, varscan2
- DHX16 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs768833519, COSV53312776; called by muse, mutect2, varscan2
- DHX34 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199664950, COSV60894536; called by muse, mutect2, varscan2
- DHX40 | c.1060A>T p.I354L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV52066304; called by muse, mutect2, varscan2
- DHX8 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1341366727, COSV52251317; called by muse, mutect2, varscan2
- DIDO1 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56615143; called by muse, mutect2, varscan2
- DIP2A | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371626954; called by muse, mutect2, varscan2
- DISP3 | c.3005G>T p.R1002L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53819770, COSV53821663; called by muse, mutect2
- DLEC1 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV57295910; called by muse, mutect2, varscan2
- DLG5 | c.2958dup p.K987Qfs*37 | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | catalogued as rs1389184095; called by mutect2, pindel, varscan2
- DLGAP4 | c.2242G>A p.G748S (on ENST00000339266 / NM_001365621.1; = p.G745S on NM_014902.6) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs376006423, COSV59415023; called by muse, mutect2, varscan2
- DLK1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs191731751, COSV57990804; called by muse, mutect2, varscan2
- DMBT1 | c.3014G>A p.R1005Q (on ENST00000338354 / NM_001377530.1; = p.R506Q on NM_004406.3) | Missense Mutation (SNP) | VAF 96/627 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs753951872, COSV100352985, COSV57536368; called by muse, mutect2, varscan2
- DMD | c.9980G>T p.R3327M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58894554; called by mutect2, varscan2
- DMRT3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51902744; called by muse, mutect2
- DNAH1 | c.8237C>T p.P2746L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548600793, COSV70226879; called by muse, mutect2
- DNAH5 | c.8875G>A p.G2959R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147443285; called by muse, mutect2, varscan2
- DNAH9 | c.11821G>A p.V3941M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52337133; called by muse, mutect2, varscan2
- DND1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV100297992; called by muse, mutect2
- DNM2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100117095, COSV58957696; called by muse, mutect2, varscan2
- DOCK10 | c.6065C>T p.S2022L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51352728; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK2 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV56944823; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs782552436; called by pindel, varscan2
- DOP1B | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs766473651, COSV67692310; called by muse, mutect2, varscan2
- DPH1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs1294206597, COSV53983844; called by muse, mutect2
- DRC1 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56529481; called by muse, mutect2, varscan2
- DROSHA | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV60773192; called by muse, mutect2
- DSCAML1 | c.3001T>C p.S1001P (on ENST00000321322; = p.S941P on NM_020693.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); catalogued as COSV58380146, COSV58383137; called by muse, mutect2, varscan2
- DSCAML1 | c.1673C>T p.A558V (on ENST00000321322; = p.A498V on NM_020693.4) | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV58383151; called by muse, mutect2, varscan2
- DST | c.13182del p.V4395Ffs*13 (on ENST00000361203 / NM_001374722.1; = p.V1983Ffs*13 on NM_015548.5) | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs1190969813; called by mutect2, pindel, varscan2
- DYM | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201686059; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- ECH1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200226678, COSV55488714; called by muse, mutect2, varscan2
- EEF2K | c.586del p.E196Rfs*22 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs1567276794; called by mutect2, pindel, varscan2
- EFCAB6 | c.4009G>A p.V1337M | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as rs142679598; called by muse, mutect2, varscan2
- EFNA4 | c.535del p.D179Tfs*15 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs754580525; called by mutect2, pindel, varscan2
- EGFL8 | c.148_150del p.N50del | In Frame Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs774671618; called by mutect2, pindel, varscan2
- EGR2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54346321; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567del p.L856Wfs*7 | Frame Shift Del (DEL) | VAF 63/275 reads (23%) | catalogued as rs35250897; called by mutect2, pindel, varscan2
- EIF2B5 | c.1036T>C p.S346P (on ENST00000647909; = p.S338P on NM_003907.3) | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV56603810; called by muse, mutect2, varscan2
- EIF3B | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.571); catalogued as COSV62802834; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1193020773, COSV57514804; called by muse, mutect2, varscan2
- EIF5A2 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV55542577; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELL2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV52981391, COSV99031722; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | catalogued as rs766700925; called by mutect2, varscan2
- ENKUR | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV58632511; called by muse, mutect2, varscan2
- ENOX1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV54889149; called by muse, mutect2, varscan2
- ENPP3 | c.1772A>G p.Q591R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62953182; called by muse, mutect2, varscan2
- ENTPD4 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778190156, COSV62268376; called by muse, mutect2, varscan2
- EP400 | c.7940C>T p.A2647V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1443847067, COSV57764655; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHA5 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1439259258, COSV56633589, COSV56640546; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 28/110 reads (25%) | catalogued as rs765115164; called by mutect2, varscan2
- EPPK1 | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs782353672, COSV73260891; called by muse, mutect2, varscan2
- EPS8L1 | c.1086dup p.P363Afs*28 (on ENST00000201647 / NM_133180.3; = p.P236Afs*28 on NM_017729.3) | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs746955003; called by mutect2, varscan2
- ERAP1 | c.2470G>T p.G824* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV57085501; called by muse, mutect2, varscan2
- ERBB3 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403278713, COSV57247278, COSV57260257; called by muse, mutect2, varscan2
- ERMARD | c.960+1G>C p.X320_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV64647636; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1309653898; called by mutect2, pindel
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53829732; called by muse, mutect2, varscan2
- EXOSC4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as rs1554763298, COSV60155356; called by muse, mutect2, varscan2
- EYA1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV58157769; called by muse, mutect2, varscan2
- EYA2 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs371083777; called by muse, mutect2, varscan2
- EZHIP | c.1262T>C p.I421T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100539630; called by muse, mutect2, varscan2
- F7 | c.610dup p.R204Kfs*77 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | catalogued as rs1288996601; called by mutect2, pindel, varscan2
- FAM120C | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV100069596, COSV60257769; called by muse, mutect2
- FAM131B | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.083); catalogued as COSV68125599; called by muse, mutect2, varscan2
- FAM135B | c.3620T>A p.L1207H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52708742; called by muse, mutect2, varscan2
- FAM160B2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs774274007, COSV57157199; called by muse, mutect2
- FAM186B | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.217); catalogued as rs756366808, COSV57720624, COSV57721943; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM214A | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as rs1233955467, COSV55922462; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs746881923; called by mutect2, varscan2
- FAM43A | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs536961614, COSV61672769; called by muse, mutect2, varscan2
- FAM47B | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs200918267, COSV61452687, COSV61453630; called by muse, mutect2, varscan2
- FAM47C | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); catalogued as COSV63723806; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FANCM | c.2228C>A p.P743H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57497884; called by muse, mutect2, varscan2
- FASN | c.7242G>T p.Q2414H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60751118; called by muse, mutect2, varscan2
- FAT4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.988); catalogued as COSV67882083; called by muse, mutect2, varscan2
- FBN2 | c.6610C>T p.L2204F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs201541140, COSV52496151; called by muse, mutect2, varscan2
- FBXL7 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV100310972, COSV61641991; called by muse, mutect2, varscan2
- FBXO11 | c.1471A>G p.T491A (on ENST00000403359 / NM_001190274.2; = p.T407A on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV57016828; called by muse, mutect2, varscan2
- FBXO39 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs996532924, COSV58621162; called by muse, mutect2, varscan2
- FBXO40 | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57522269; called by muse, mutect2, varscan2
- FBXO43 | c.1969C>A p.L657M | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV71053438; called by muse, mutect2, varscan2
- FBXW4 | c.1681G>A p.V561I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs750201843, COSV58706895; called by muse, mutect2, varscan2
- FBXW8 | c.572G>A p.R191H (on ENST00000309909; = p.R229H on NM_012174.1) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576076851, COSV59296975; called by muse, mutect2, varscan2
- FBXW9 | c.1174G>A p.A392T (on ENST00000587955; = p.A372T on NM_032301.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs199707156, COSV66709351; called by muse, mutect2, varscan2
- FCGR2C | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.636); catalogued as rs1335311228, COSV63434620; called by muse, mutect2, varscan2
- FCHSD2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs769026499, COSV60807010; called by muse, mutect2
- FCRL1 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV63824071; called by muse, mutect2, varscan2
- FCRL5 | c.2674T>C p.S892P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs780989771, COSV62512089; called by muse, mutect2, varscan2
- FDXR | c.1111G>A p.V371M (on ENST00000293195 / NM_024417.5; = p.V377M on NM_004110.6) | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs375884169; called by muse, mutect2, varscan2
- FEM1C | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57230864; called by muse, mutect2, varscan2
- FERMT1 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54091326; called by muse, mutect2, varscan2
- FERMT2 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 34/138 reads (25%) | catalogued as COSV58405470; called by muse, mutect2, varscan2
- FES | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs765951710, COSV51574960; called by muse, mutect2, varscan2
- FFAR2 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771538131, COSV55831863; called by muse, mutect2, varscan2
- FGD3 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs200349085; called by muse, mutect2, varscan2
- FGFBP1 | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV52586121; called by muse, varscan2
- FGFR1 | c.2009A>G p.E670G (on ENST00000447712 / NM_023110.3; = p.E668G on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM114758, COSV58329220; called by muse, mutect2, varscan2
- FIGNL1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772460200, COSV63553255; called by muse, mutect2, varscan2
- FIP1L1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60994038; called by muse, mutect2, varscan2
- FLNC | c.6212A>G p.Y2071C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57951536; called by muse, mutect2, varscan2
- FLT1 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as rs745653714, COSV56718562; called by muse, mutect2, varscan2
- FLT4 | c.1088del p.P363Rfs*27 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as COSV99985814; called by mutect2, pindel, varscan2
- FLT4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV56100260; called by muse, mutect2, varscan2
- FMN2 | c.5045T>G p.L1682R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV60419417, COSV60456884; called by muse, mutect2, varscan2
- FMNL1 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV58955477; called by muse, mutect2, varscan2
- FMNL3 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs762982824, COSV53298481; called by muse, mutect2, varscan2
- FN3K | c.851A>C p.N284T | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV56181449; called by muse, mutect2, varscan2
- FNBP1L | c.1710G>T p.E570D (on ENST00000271234 / NM_001164473.2; = p.E512D on NM_017737.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773891724, COSV53091792; called by muse, mutect2, varscan2
- FOXD4L4 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1159773491; called by mutect2, varscan2
- FOXN1 | c.1748del p.P583Lfs*5 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs1298276474; called by mutect2, pindel, varscan2
- FOXP4 | c.1235del p.P412Rfs*77 (on ENST00000307972 / NM_001012426.1; = p.P399Rfs*77 on NM_138457.3) | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as COSV57223583; called by mutect2, pindel, varscan2
- FRK | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73383832; called by muse, mutect2, varscan2
- FSIP2 | c.19220A>G p.E6407G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV100554822; called by muse, mutect2, varscan2
- FUT1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs750207214, COSV59567592; called by muse, mutect2, varscan2
- FUT2 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.444); catalogued as rs370886251; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs756304971; called by mutect2, varscan2
- FXR1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV59761344; called by muse, mutect2, varscan2
- FYB1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs778016126, COSV60941745; called by muse, mutect2, varscan2
- GAA | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs770021831, COSV100162997; ClinVar: uncertain significance; called by mutect2, varscan2
- GABBR1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770127438, COSV100589571, COSV63541166; called by muse, mutect2, varscan2
- GABRB2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs373324958, COSV50903874; ClinVar: uncertain significance; called by muse, varscan2
- GAL3ST1 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV58892017, COSV99065546; called by muse, mutect2, varscan2
- GALNT18 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57144843; called by muse, mutect2, varscan2
- GAS1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV53926669; called by muse, mutect2
- GCC1 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50000388; called by muse, mutect2
- GCSAM | c.151dup p.I51Nfs*5 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs762814436; called by mutect2, varscan2
- GFOD1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64954339; called by muse, mutect2, varscan2
- GFRAL | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs527946821, COSV61229141, COSV61236470; called by muse, mutect2, varscan2
- GGA1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs762217256, COSV57329031; called by muse, mutect2, varscan2
- GJA4 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs758289830, COSV60724588; called by muse, mutect2, varscan2
- GJB4 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1403929835, COSV58355605; called by muse, mutect2
- GLA | c.151A>G p.M51V | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV54508295; called by muse, mutect2
- GLI1 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs767216717, COSV57358586; called by muse, mutect2, varscan2
- GLI3 | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101230266, COSV67885736; called by muse, mutect2
- GLI3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs186337909; ClinVar: likely benign; called by muse, mutect2
- GLIS3 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV60924775; called by muse, mutect2
- GLT8D2 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV62561195; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGB1 | c.7619T>C p.L2540P | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61462345; called by muse, mutect2, varscan2
- GPATCH8 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59193394; called by muse, mutect2, varscan2
- GPNMB | c.1300G>A p.E434K (on ENST00000381990 / NM_001005340.2; = p.E422K on NM_002510.3) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs752209898, COSV51697108; called by muse, varscan2
- GPR101 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1407653855, COSV53237635; called by muse, mutect2, varscan2
- GPR182 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as rs761208615, COSV55625592; called by muse, mutect2, varscan2
- GPR27 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs1412434806, COSV55203061; called by muse, mutect2, varscan2
- GPR61 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437368510, COSV68177318; called by muse, mutect2, varscan2
- GRAMD1A | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs749587215, COSV58766006, COSV58769025; called by muse, mutect2, varscan2
- GRK7 | c.1082T>C p.I361T | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53821750; called by muse, mutect2, varscan2
- GRM1 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1347532771, COSV51111362; called by muse, mutect2, varscan2
- GRM4 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562013185, COSV65211150; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GSDMC | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs140640562, COSV52699295; called by muse, mutect2, varscan2
- GULP1 | c.44A>G p.H15R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1367876483, COSV63065379; called by muse, mutect2, varscan2
- H2AC8 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55126309; called by muse, mutect2, varscan2
- H2AC8 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55126312; called by muse, mutect2, varscan2
- HACE1 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53499613; called by muse, mutect2, varscan2
- HAGH | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs1054333380, COSV68400249; called by muse, mutect2
- HCN1 | c.2294del p.N765Mfs*15 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as COSV57515469; called by pindel, varscan2
- HCN1 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57496122; called by muse, mutect2, varscan2
- HDAC4 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs549858743, COSV61860532; called by muse, mutect2, varscan2
- HDHD2 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV56075374; called by muse, mutect2, varscan2
- HEATR1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.184); catalogued as rs371395131; called by muse, mutect2, varscan2
- HECTD1 | c.2497-2A>G p.X833_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV65991138; called by mutect2, varscan2
- HECTD4 | c.6209G>A p.R2070H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66387540; called by muse, mutect2
- HELLS | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV53294818; called by muse, mutect2, varscan2
- HERC1 | c.12948del p.S4317Afs*9 | Frame Shift Del (DEL) | VAF 63/293 reads (22%) | catalogued as COSV71248405; called by mutect2, pindel, varscan2
- HERC2 | c.9737G>A p.R3246Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV55310567; called by muse, mutect2, varscan2
- HERC2 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.838); catalogued as rs1311675966, COSV55310595; called by muse, mutect2, varscan2
- HEY1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61232408; called by muse, mutect2, varscan2
- HGFAC | c.1801C>G p.P601A | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775128737, COSV66976662; called by muse, mutect2, varscan2
- HHATL | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs149595115; called by muse, mutect2, varscan2
- HHIPL2 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58563364; called by muse, mutect2, varscan2
- HIC2 | c.899del p.G300Afs*17 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs1388756225, COSV68041693; called by mutect2, pindel, varscan2
- HIPK2 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs550978102, COSV61226047, COSV61230529; called by muse, mutect2, varscan2
- HIPK3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs376939727, COSV57561140; called by muse, varscan2
- HMCN1 | c.3524G>A p.R1175H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs527332989, COSV54881305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPM | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.166); catalogued as rs746414049, COSV55312225; called by muse, mutect2, varscan2
- HNRNPUL1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54560405; called by muse, mutect2, varscan2
- HOXA10 | c.152del p.G51Afs*53 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1562511344, CM131800; called by mutect2, varscan2
- HTR3A | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV55468182; called by muse, mutect2, varscan2
- HUWE1 | c.10093C>T p.R3365W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1382319906, COSV53335438, COSV99474484; called by muse, mutect2
- HYAL2 | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63305965; called by muse, mutect2, varscan2
- HYOU1 | c.1892A>C p.E631A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV68215254; called by muse, mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | catalogued as rs747841314; called by mutect2, varscan2
- IFI16 | c.1969C>T p.R657* (on ENST00000295809 / NM_001364867.2; = p.R601* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as rs747530999, COSV55531565; called by muse, mutect2, varscan2
- IFIT2 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769134303, COSV51078061, COSV51080184; called by muse, mutect2, varscan2
- IFT172 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV53130696; called by muse, mutect2, varscan2
- IFT74 | c.404+2T>C p.X135_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV66286024; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs975701822, COSV63626823; called by muse, mutect2, varscan2
- IGSF10 | c.7853C>T p.T2618M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376416108; called by muse, mutect2, varscan2
- IL16 | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV57261005; called by muse, mutect2, varscan2
- IL17RB | c.567_569del p.K189del | In Frame Del (DEL) | VAF 22/89 reads (25%) | catalogued as rs1189226312; called by pindel, varscan2
- IL23R | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767358325, COSV61373073; called by muse, mutect2, varscan2
- IL4R | c.2050del p.E684Kfs*3 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs1201023196; called by mutect2, pindel, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INHBA | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV54219824; called by muse, mutect2, varscan2
- INHBA | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 150/552 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54219829; called by muse, mutect2, varscan2
- INKA2 | c.559dup p.A187Gfs*3 | Frame Shift Ins (INS) | VAF 16/80 reads (20%) | catalogued as rs751997684; called by mutect2, varscan2
- INSC | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65409085; called by muse, mutect2, varscan2
- INTS8 | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as rs1417004170, COSV57375088; called by muse, mutect2, varscan2
- INVS | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150883233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO9 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64232921; called by muse, mutect2, varscan2
- IRAG1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368966460, COSV70211482; called by muse, mutect2, varscan2
- IREB2 | c.1561A>G p.M521V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs553171458, COSV51920923; called by muse, mutect2, varscan2
- IREB2 | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375120202; called by muse, mutect2, varscan2
- IRF4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as rs1302327519, COSV66704534; called by muse, mutect2, varscan2
- IRS4 | c.2894G>C p.G965A | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV64532822, COSV64535935; called by muse, mutect2, varscan2
- IRX6 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs954710287, COSV51859402; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- ITGA4 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs901057020, COSV51998204; called by muse, mutect2, varscan2
- ITGA4 | c.1540G>T p.V514F | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV51998213; called by muse, mutect2, varscan2
- ITGA6 | c.681del p.F227Lfs*3 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as COSV99905555; called by mutect2, pindel, varscan2
- ITGA7 | c.2525G>A p.R842Q (on ENST00000555728; = p.R798Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs923021284, COSV57692493; ClinVar: uncertain significance; called by muse, varscan2
- ITGAV | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200949549, COSV53709675; called by muse, mutect2, varscan2
- ITGB1 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478983; called by muse, mutect2
- ITGB7 | c.2316+1G>A p.X772_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV57237907; called by muse, mutect2, varscan2
- ITIH5 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs199952014, COSV53660667; called by muse, mutect2, varscan2
- ITPR3 | c.7967G>A p.R2656H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs1252902879, COSV65267961; called by muse, mutect2, varscan2
- JAK1 | c.3369G>T p.E1123D | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV53805241; called by muse, mutect2
- JARID2 | c.1186dup p.A396Gfs*25 | Frame Shift Ins (INS) | VAF 28/115 reads (24%) | catalogued as rs778734711; called by mutect2, varscan2
- JCAD | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs372187301, COSV64759463; called by muse, mutect2, varscan2
- JCAD | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772446869, COSV64758239; called by muse, mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as rs1226801045; called by mutect2, varscan2
- JMJD8 | c.526del p.V176Cfs*13 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs1159827834; called by mutect2, pindel, varscan2
- KAT6A | c.4367T>C p.L1456P | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55903409; called by muse, mutect2, varscan2
- KAT6A | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.644); catalogued as rs377324520; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCND1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs375813023, COSV54412853; called by muse, mutect2, varscan2
- KCNH3 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs756947702, COSV57789831; called by muse, mutect2, varscan2
- KCNJ10 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1280213852, COSV63632940; called by muse, mutect2, varscan2
- KCNK10 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as rs1163487185, COSV56640205; called by muse, mutect2, varscan2
- KCNN2 | c.424G>A p.G142S (on ENST00000264773; = p.G354S on NM_021614.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1264955648, COSV53284074; called by muse, mutect2, varscan2
- KCTD10 | c.474+2T>C p.X158_splice | Splice Site (SNP) | VAF 13/72 reads (18%) | catalogued as COSV57325991; called by muse, mutect2, varscan2
- KIAA1549L | c.5287A>G p.I1763V (on ENST00000321505; = p.I2060V on NM_012194.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as rs765990826, COSV58582906; called by muse, mutect2
- KIAA1755 | c.3492dup p.R1165Qfs*25 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | catalogued as rs772495335; called by mutect2, pindel, varscan2
- KIAA1755 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV54074273; called by muse, mutect2, varscan2
- KIF11 | c.2922+2T>C p.X974_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53269003; called by muse, mutect2, varscan2
- KIF16B | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.052); catalogued as COSV61702020; called by muse, mutect2, varscan2
- KLC3 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV67266842; called by muse, mutect2, varscan2
- KLC3 | c.1443G>T p.Q481H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV67266845; called by muse, mutect2, varscan2
- KLF4 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs747114701, COSV65928656; called by muse, mutect2, varscan2
- KLHL14 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs772519652, COSV63830877; called by muse, mutect2, varscan2
- KLHL15 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60139331; called by muse, mutect2, varscan2
- KLHL28 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754456839, COSV61887493; called by muse, mutect2, varscan2
- KLHL36 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50718178; called by muse, mutect2, varscan2
- KLHL4 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64139570; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 44/180 reads (24%) | catalogued as COSV52930337; called by mutect2, varscan2
- KMT2A | c.6235G>A p.V2079I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1555045463, COSV63282749; called by muse, mutect2, varscan2
- KMT2D | c.7634C>A p.P2545H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56415631; called by muse, mutect2, varscan2
- KMT2E | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs780716600, COSV57570081; called by muse, mutect2, varscan2
- KNDC1 | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs766387008, COSV58831441; called by muse, mutect2, varscan2
- KREMEN1 | c.637G>A p.A213T (on ENST00000407188; = p.A215T on NM_032045.5) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs369566037; called by muse, mutect2, varscan2
- KRT1 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1372943322, COSV52865241; called by muse, mutect2, varscan2
- KRT32 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56785664; called by muse, mutect2, varscan2
- KRT33A | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as rs1567666399; called by mutect2, pindel
- KRT36 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.596); catalogued as COSV60202669; called by muse, mutect2
- KRT38 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs371008046; called by muse, mutect2, varscan2
- KSR2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs185272487, COSV56667008; called by muse, mutect2, varscan2
- L3MBTL3 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as COSV62384578; called by muse, mutect2, varscan2
- LAMA1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV67532944; called by muse, mutect2, varscan2
- LAMB2 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs754337557, COSV59731304; called by muse, mutect2, varscan2
- LAMB4 | c.4903C>T p.Q1635* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as rs374793818; called by muse, mutect2, varscan2
- LAMC1 | c.1991-2A>G p.X664_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51133626; called by muse, mutect2, varscan2
- LAMC3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs141325432; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBR | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV55287710; called by muse, mutect2, varscan2
- LCOR | c.911T>C p.M304T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63630216; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LEP | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV58240690; called by muse, mutect2, varscan2
- LGR4 | c.2102C>T p.T701M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs369897268; called by muse, mutect2, varscan2
- LIFR | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54684660, COSV54684830; called by muse, mutect2, varscan2
- LILRB1 | c.587_589del p.G196del (on ENST00000427581; = p.G160del on NM_006669.6) | In Frame Del (DEL) | VAF 28/216 reads (13%) | catalogued as rs1298312608; called by mutect2, varscan2
- LIPH | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371942576; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMCD1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50087399; called by muse, mutect2, varscan2
- LNPEP | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs371529503; called by muse, mutect2, varscan2
- LNPK | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55822649; called by muse, mutect2, varscan2
- LONRF3 | c.1928G>A p.R643Q (on ENST00000371628 / NM_001031855.3; = p.R602Q on NM_024778.5) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1484324014, COSV59150323; called by muse, mutect2, varscan2
- LRFN3 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371303691, COSV55817070; called by muse, mutect2
- LRIT1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as rs750253759, COSV64512047; called by muse, mutect2, varscan2
- LRP1 | c.8794G>A p.D2932N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763968301, COSV54503445; called by muse, mutect2, varscan2
- LRP1B | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs768074082, COSV63341619, COSV63342088; called by muse, mutect2
- LRRC20 | c.547dup p.L183Pfs*59 (on ENST00000355790 / NM_207119.3; = p.L127Pfs*59 on NM_018205.4) | Frame Shift Ins (INS) | VAF 15/101 reads (15%) | catalogued as rs768741708; called by mutect2, pindel, varscan2
- LRRC29 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58526591; called by muse, mutect2, varscan2
- LRRC37A2 | c.3493A>C p.K1165Q | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100238708; called by muse, varscan2
- LRRC37A3 | c.3917G>A p.R1306H | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs764013252, COSV58534186, COSV58534207; called by muse, mutect2, varscan2
- LRRC41 | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV58439061; called by muse, mutect2, varscan2
- LRRC7 | c.4006A>G p.M1336V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as COSV50416460; called by muse, mutect2, varscan2
- LRRC8A | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs1367994080, COSV52184247; called by muse, mutect2, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRIQ4 | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV61618733; called by muse, mutect2, varscan2
- LRRN4 | c.979_980del p.K327Efs*84 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs764789750; called by mutect2, pindel, varscan2
- LTBP4 | c.4814G>A p.R1605H (on ENST00000308370 / NM_001042544.1; = p.R1568H on NM_003573.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.615); catalogued as rs777450656, COSV52577027; called by muse, mutect2, varscan2
- LURAP1L | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1156496659, COSV100070693, COSV59983765; called by muse, mutect2, varscan2
- LYPLA1 | c.167+1G>A p.X56_splice | Splice Site (SNP) | VAF 13/82 reads (16%) | catalogued as rs1346569181, COSV57604218; called by muse, mutect2, varscan2
- LZTR1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs776112712, COSV53145563; called by muse, mutect2, varscan2
- MAB21L2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58260992; called by muse, mutect2, varscan2
- MAGEA6 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61448699; called by muse, mutect2, varscan2
- MAGEB1 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as rs757496879, COSV66775298; called by muse, mutect2, varscan2
- MAGT1 | c.184C>T p.R62C (on ENST00000618282 / NM_001367916.1; = p.R94C on NM_032121.5) | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63780960; called by muse, mutect2, varscan2
- MAMLD1 | c.2284+1G>C p.X762_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53372480; called by muse, mutect2
- MAN2B2 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV53450956; called by muse, mutect2, varscan2
- MAPK15 | c.1538del p.G513Vfs*? | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as rs782558070; called by mutect2, pindel, varscan2
- MAPK8IP1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs141639373; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs777328830; called by mutect2, varscan2
- MARCO | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs748412045, COSV59052272; called by muse, mutect2, varscan2
- MAST4 | c.7640G>A p.R2547Q (on ENST00000403625 / NM_001164664.2; = p.R2358Q on NM_015183.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.022); catalogued as rs1436491489, COSV55117354; called by muse, mutect2, varscan2
- MBD3L1 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59775738; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 36/182 reads (20%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MBOAT1 | c.865A>G p.M289V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV61123797; called by muse, mutect2, varscan2
- MCF2 | c.2251T>C p.S751P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV58479066; called by muse, mutect2, varscan2
- MCHR1 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV50760429; called by muse, mutect2, varscan2
- MCM5 | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV53345181; called by muse, mutect2, varscan2
- MCOLN1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs780449062, COSV51174175; called by muse, mutect2, varscan2
- MDN1 | c.16163C>T p.A5388V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65518023; called by muse, mutect2, varscan2
- MELK | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs769461815, COSV53197281; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs745891632; called by mutect2, varscan2
- MFSD10 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752294519, COSV53266709; called by muse, mutect2, varscan2
- MGAM | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1163875284, COSV72073816; called by muse, mutect2, varscan2
- MGAM | c.3016A>G p.S1006G | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV72073837; called by muse, mutect2, varscan2
- MICB | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs371170217; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINDY2 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV57505670; called by muse, mutect2
- MKS1 | c.916-2A>G p.X306_splice | Splice Site (SNP) | VAF 5/81 reads (6%) | catalogued as COSV58302788; called by muse, mutect2
- MMP3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147533686; called by muse, mutect2, varscan2
- MOGAT2 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs576205474, COSV52218570; called by muse, mutect2, varscan2
- MROH1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs778259777, COSV58187774; called by muse, mutect2, varscan2
- MRPL10 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs760722918, COSV51619441; called by muse, mutect2, varscan2
- MRTFA | c.306G>A p.P102= | Splice Region (SNP) | VAF 43/193 reads (22%) | catalogued as rs868096885, COSV62931620; called by muse, mutect2, varscan2
- MS4A15 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61960904; called by muse, mutect2, varscan2
- MSH3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs748207601, COSV54145699; called by muse, mutect2, varscan2
- MSH5 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65208813; called by muse, mutect2, varscan2
- MST1R | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56565368; called by muse, mutect2, varscan2
- MTERF3 | c.1060-2A>G p.X354_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99749099; called by muse, mutect2
- MTHFD1 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53698175; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs767880823; called by mutect2, varscan2
- MTUS1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs1285880321, COSV50551270; called by muse, mutect2, varscan2
- MTUS2 | c.3640G>A p.E1214K (on ENST00000612955 / NM_001366650.1; = p.E193K on NM_015233.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775222983, COSV66420118, COSV66421290; called by muse, mutect2, varscan2
- MUC16 | c.41593C>T p.R13865C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs367857280, COSV66690229; called by muse, mutect2, varscan2
- MUC16 | c.40520C>T p.T13507M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs375872439; called by muse, mutect2, varscan2
- MXRA5 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs146747759, COSV54225713; called by muse, mutect2, varscan2
- MYCBP2 | c.13730A>G p.H4577R (on ENST00000357337; = p.H4615R on NM_015057.5) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100632790, COSV62011569; called by muse, mutect2, varscan2
- MYCBPAP | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as COSV60405676; called by muse, mutect2, varscan2
- MYH3 | c.1005C>T p.S335= | Splice Region (SNP) | VAF 20/80 reads (25%) | catalogued as rs142547724; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 26/108 reads (24%) | catalogued as rs761123152; called by mutect2, varscan2
- MYH6 | c.4159G>T p.E1387* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV62448280; called by muse, mutect2, varscan2
- MYH7B | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs369138767; called by muse, mutect2, varscan2
- MYH7B | c.5816C>A p.T1939N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV52677337; called by muse, mutect2, varscan2
- MYLK2 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65658652, COSV65658974; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18A | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs371862120; called by muse, mutect2
- MYO7B | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV67345049; called by muse, mutect2, varscan2
- MYOG | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as rs752485385, COSV54095108; called by muse, mutect2, varscan2
- MYOM1 | c.4838T>C p.L1613P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55286510; called by muse, mutect2, varscan2
- NAPG | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59796422; called by muse, mutect2, varscan2
- NAV1 | c.3632del p.K1211Rfs*17 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs770039235; called by mutect2, varscan2
- NBAS | c.5518A>G p.M1840V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as COSV55714026; called by muse, mutect2, varscan2
- NBAS | c.2246G>A p.G749D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs544578792, COSV55714039, COSV55740912; called by muse, mutect2, varscan2
- NBEA | c.8275A>G p.I2759V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV59763797; called by mutect2, varscan2
- NBPF3 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.068); catalogued as rs1415896546, COSV59057176; called by muse, mutect2, varscan2
- NCAM2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763784898, COSV53059389; called by muse, mutect2, varscan2
- NDRG1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774885520, COSV60482698; called by muse, mutect2, varscan2
- NDRG3 | c.813C>T p.V271= (on ENST00000349004 / NM_032013.4; = p.V259= on NM_022477.4) | Splice Region (SNP) | VAF 14/85 reads (16%) | catalogued as rs777659603, COSV62421148; called by muse, mutect2, varscan2
- NEB | c.14472del p.D4825Tfs*27 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | catalogued as COSV51414756; called by mutect2, pindel, varscan2
- NEFL | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs538481538; called by muse, mutect2
- NEIL3 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52808855; called by muse, varscan2
- NEPRO | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34351095; called by muse, mutect2, varscan2
- NHLRC2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs558242040, COSV65174470; called by muse, mutect2, varscan2
- NINJ1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV64922516; called by muse, mutect2, varscan2
- NINL | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53999144; called by muse, mutect2, varscan2
- NIPBL | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs939532340, COSV56944110; called by muse, mutect2, varscan2
- NKRF | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58660877, COSV58662657; called by muse, mutect2, varscan2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1402340327; called by mutect2, pindel
- NOL4 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV52337674; called by muse, mutect2, varscan2
- NOMO1 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV55060621, COSV99814413; called by muse, mutect2, varscan2
- NOS1 | c.3899A>C p.E1300A | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57607820; called by muse, mutect2, varscan2
- NOTCH1 | c.6151G>T p.G2051W | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53032446, COSV53053570; called by muse, mutect2, varscan2
- NOXRED1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775418298, COSV53627596; called by muse, mutect2, varscan2
- NPC1 | c.2509A>T p.I837F | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as CD045443, CM125221, COSV52576715; called by muse, mutect2, varscan2
- NPTN | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV54736899; called by muse, mutect2, varscan2
- NPTX1 | c.445-1G>A p.X149_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100151223, COSV60774416; called by muse, mutect2
- NPY | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs535222320, COSV54214679; called by muse, mutect2, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs779801455; called by mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs774343392; called by mutect2, varscan2
- NRAP | c.3829C>T p.R1277C (on ENST00000359988 / NM_001322945.2; = p.R1242C on NM_006175.4) | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1452260134, COSV63488817; called by muse, mutect2, varscan2
- NRAP | c.3785C>T p.T1262M (on ENST00000359988 / NM_001322945.2; = p.T1227M on NM_006175.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs752746771, COSV63488819; called by muse, mutect2, varscan2
- NRG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV64547336; called by muse, mutect2, varscan2
- NRN1L | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1044247559, COSV59302081; called by muse, mutect2, varscan2
- NRXN3 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV73581780; called by muse, mutect2, varscan2
- NSD1 | c.5556del p.E1853Sfs*2 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as COSV61774471; called by mutect2, pindel, varscan2
- NTNG1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774800384, COSV53964408; called by muse, mutect2, varscan2
- NTRK1 | c.1354+1G>A p.X452_splice | Splice Site (SNP) | VAF 22/87 reads (25%) | catalogued as rs764771898, COSV62323803, COSV62326521; called by muse, mutect2, varscan2
- NUAK1 | c.101T>G p.L34R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs751592845, COSV54600993; called by muse, mutect2, varscan2
- NUDT11 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65664995; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 38/222 reads (17%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP160 | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65853704; called by muse, mutect2, varscan2
- OAZ3 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as COSV100162500; called by muse, mutect2, varscan2
- OBSCN | c.4237T>C p.C1413R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.046); catalogued as COSV52747034, COSV52771736; called by muse, mutect2, varscan2
- OBSL1 | c.5435G>A p.R1812H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54703828; called by mutect2, varscan2
- OBSL1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756906456, COSV54713850; called by muse, mutect2, varscan2
- OGDHL | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757281565, COSV65101260; called by muse, mutect2, varscan2
- OLFM4 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54576062; called by muse, mutect2, varscan2
- OPCML | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59407788; called by muse, mutect2, varscan2
- OPRK1 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.136); catalogued as COSV55568690, COSV55568717; called by muse, mutect2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2T2 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100737638; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 70/308 reads (23%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52N4 | c.964T>C p.*322Rext*7 | Nonstop Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV57890435; called by muse, mutect2, varscan2
- OR5AR1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs750172475, COSV57252941; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5M10 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV101595881; called by muse, mutect2, varscan2
- OR6B1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs923564337, COSV68769841; called by muse, mutect2, varscan2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR6K2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs771457648, COSV62743156; called by muse, mutect2, varscan2
- OR6Y1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56928377, COSV56929347; called by muse, mutect2, varscan2
- OR8G5 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as COSV100422371; called by muse, mutect2, varscan2
- OR8H1 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339383790, COSV57293235; called by muse, mutect2, varscan2
- OR9K2 | c.260dup p.L88Pfs*8 (on ENST00000305377; = p.L66Pfs*8 on NM_001005243.1) | Frame Shift Ins (INS) | VAF 57/264 reads (22%) | catalogued as rs1163883585; called by mutect2, pindel, varscan2
- OR9K2 | c.580del p.C194Afs*29 (on ENST00000305377; = p.C172Afs*29 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | catalogued as COSV59531612, COSV59532766; called by mutect2, pindel, varscan2
- OSBPL6 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.629); catalogued as COSV51912105; called by muse, mutect2, varscan2
- OSMR | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs372089425; called by muse, mutect2, varscan2
- OTOA | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149668552; called by muse, mutect2, varscan2
- OTOF | c.5593A>G p.T1865A (on ENST00000272371 / NM_194248.3; = p.T1098A on NM_004802.4) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV55497188; called by muse, mutect2, varscan2
- OTOP2 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs760162062, COSV58880844; called by muse, mutect2, varscan2
- OTOR | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55721683; called by muse, mutect2, varscan2
- OTUD6B | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53442114; called by muse, mutect2
- OXTR | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV57478553; called by muse, mutect2
- PAFAH1B1 | c.1118T>C p.M373T | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV68210035; called by muse, mutect2, varscan2
- PALD1 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54971172; called by muse, mutect2, varscan2
- PALD1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs766925536, COSV54971183; called by muse, mutect2, varscan2
- PARD3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762819451, COSV60745962; called by muse, mutect2, varscan2
- PARP10 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs781999070, COSV57296906, COSV57299465; called by muse, mutect2
- PATJ | c.5200C>T p.P1734S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.399); catalogued as COSV64501414; called by muse, mutect2, varscan2
1,213 further variants in this file (721 protein-altering or splice-affecting, 433 silent, 59 other) are not listed here.
